Somatic mutation profile of tumor specimen TCGA-BC-A10Q-01A (aliquot TCGA-BC-A10Q-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10Q, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Age at diagnosis: 72.3 years (26,400 days).
Specimen TCGA-BC-A10Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3fa1385-1102-4c80-99d2-c64534904e46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10Q-11A (Solid Tissue Normal), aliquot TCGA-BC-A10Q-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c77f17d-87af-4a15-b2df-bf66391ae800

The open-access MAF lists 46 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 13, Frame Shift Del 3, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1, Intron 1, In Frame Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 87/180 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RAF1 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397516828, CM073296, CM122806, CM152880, COSV52574568, COSV52583046; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5782G>T p.V1928F | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as rs762614194, COSV70025927, COSV70040945; called by muse, mutect2, varscan2
- ARID5B | c.995T>C p.M332T | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54414575; called by muse, mutect2, varscan2
- BMP15 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53139946; called by muse, mutect2, varscan2
- DMD | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 84/540 reads (16%) | catalogued as COSV63735702, COSV63756681; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs370460271, COSV62567143; called by muse, mutect2, varscan2
- H3C13 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as rs782193306, COSV58943737; called by muse, mutect2, varscan2
- HTATSF1 | c.1825A>C p.K609Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV54477395; called by muse, mutect2, varscan2
- MPRIP | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57925557; called by muse, mutect2, varscan2
- MYH2 | c.3139G>T p.E1047* | Nonsense Mutation (SNP) | VAF 15/132 reads (11%) | catalogued as COSV55431872; called by muse, mutect2, varscan2
- OAZ3 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs561852736, COSV58618115; called by muse, mutect2, varscan2
- PHKA2 | c.3008T>A p.L1003Q | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV66052569; called by muse, mutect2, varscan2
- PML | c.216T>G p.C72W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51442193; called by muse, mutect2, varscan2
- RAB24 | c.547+2T>C p.X183_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV57462854; called by mutect2, varscan2
- RANBP2 | c.3452A>G p.N1151S | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV51696204; called by muse, mutect2, varscan2
- RYR1 | c.10246G>A p.V3416M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760809784, COSV62089291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SART3 | c.1618G>A p.G540S (on ENST00000228284; = p.G522S on NM_014706.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99934339; called by muse, mutect2
- SPPL2B | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757596429, COSV71765696; called by muse, mutect2, varscan2
- STEAP4 | c.666C>G p.D222E | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV57328085; called by muse, varscan2
- TPST1 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV59174902; called by muse, mutect2, varscan2
- TTN | c.89128T>C p.S29710P (on ENST00000591111; = p.S22286P on NM_003319.4) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | PolyPhen probably damaging (0.997); catalogued as COSV59895616; called by muse, mutect2, varscan2
- U2AF2 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50035829; called by muse, mutect2, varscan2
- WDR26 | c.1954T>A p.L652I (on ENST00000414423 / NM_001379403.1; = p.L552I on NM_025160.7) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV54353221; called by muse, mutect2, varscan2
- ZNF578 | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV69735958; called by muse, mutect2
- BAP1 | c.704_712del p.P235_R237del | In Frame Del (DEL) | VAF 21/34 reads (62%) | called by mutect2, pindel, varscan2
- CYLC1 | c.600_601del p.K201Rfs*11 | Frame Shift Del (DEL) | VAF 77/259 reads (30%) | called by mutect2, pindel, varscan2
- DIP2C | c.884del p.P295Qfs*43 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- TNPO1 | c.108del p.I37Sfs*22 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- ACKR3 | c.807C>T p.H269= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs757104529, COSV56020563; called by muse, mutect2, varscan2
- ANKFY1 | c.2583C>T p.S861= (on ENST00000341657 / NM_001330063.2; = p.S862= on NM_016376.5) | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs780227998, COSV58914687; called by muse, mutect2, varscan2
- ARMH4 | c.924T>A p.S308= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV50761691; called by muse, mutect2, varscan2
- DMAP1 | c.441C>T p.L147= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV59999953; called by muse, mutect2, varscan2
- GALK2 | c.414C>T p.I138= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as COSV59099636; called by muse, mutect2, varscan2
- GALNT2 | c.1485G>A p.L495= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV64192911; called by muse, mutect2
- HK2 | c.951G>A p.E317= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs565854734, COSV51873317; called by muse, mutect2, varscan2
- KMT2A | c.6891G>A p.V2297= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV63282172; called by muse, mutect2, varscan2
- PKNOX1 | c.1122G>A p.T374= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs533645525, COSV52334215; called by muse, mutect2, varscan2
- SNX19 | c.63T>C p.N21= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV56283897; called by muse, mutect2, varscan2
- TARM1 | c.735G>A p.L245= (on ENST00000616041 / NM_001330650.1; = p.L237= on NM_001135686.3) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV71524722; called by muse, mutect2, varscan2
- TRPV3 | c.2352A>G p.E784= | Silent (SNP) | VAF 61/194 reads (31%) | catalogued as COSV56788711; called by muse, mutect2, varscan2
- ZMYND8 | c.561A>G p.E187= (on ENST00000311275 / NM_001363741.2; = p.E207= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV53683091; called by muse, mutect2, varscan2
- IGKV1-33 | c.-14A>C | 5'UTR (SNP) | VAF 32/115 reads (28%) | called by mutect2, varscan2
- RHOB | c.*501A>C | 3'UTR (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99695337; called by muse, mutect2, varscan2
- TPM4 | chr19:16076118 G>C | 5'Flank (SNP) | VAF 86/161 reads (53%) | catalogued as COSV56288049; called by muse, mutect2, varscan2
- TTN | c.34264+2908C>T | Intron (SNP) | VAF 39/151 reads (26%) | catalogued as rs1179230741, COSV59895637; called by muse, mutect2, varscan2
